Somatic mutation profile of tumor specimen 0DIOKG from CCDI case PBBVST, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.8 years (3,578 days).
Specimen 0DIOKG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65f79174-a60b-4e51-8c74-5e80ac93b48f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIOJZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2d54d85-45de-4753-92e2-5017d5158486

The open-access MAF lists 44 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 11, 3'UTR 4, Intron 2, 5'UTR 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH16A1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 75/888 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs528756148; called by muse, mutect2
- DHX15 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 171/1647 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61025899, COSV61026224; called by muse, mutect2
- DPYD | c.2507C>A p.A836D | Missense Mutation (SNP) | VAF 358/1431 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100929377; called by muse, mutect2, varscan2
- EIF3H | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 65/1433 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52666034; called by muse, mutect2
- ITIH6 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 40/1666 reads (2%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV54488361; called by muse, mutect2
- LIX1 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 274/1392 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1288073701, COSV57206437; called by muse, mutect2, varscan2
- MYH13 | c.4178C>T p.A1393V | Missense Mutation (SNP) | VAF 166/705 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1177704379; called by muse, mutect2, varscan2
- OBP2A | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 75/443 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs760517173, COSV59790956, COSV59791163; called by muse, mutect2, varscan2
- RB1 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 40/1564 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as CD952453, COSV57298288, COSV57312557; called by muse, mutect2
- RNF168 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 213/1158 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs772804181, COSV58837653; called by muse, mutect2, varscan2
- SLC35A4 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 159/882 reads (18%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.985); catalogued as rs1040812670, COSV100021485; called by muse, mutect2, varscan2
- TPRA1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 74/1440 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs372625321; called by muse, mutect2
- VPS13B | c.1949G>C p.C650S | Missense Mutation (SNP) | VAF 252/1443 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1021422161, COSV62015694; called by muse, mutect2, varscan2
- ZNF628 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as COSV52698934; called by muse, mutect2, varscan2
- ACTB | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 44/974 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- C18orf25 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 31/860 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2
- CA5B | c.385T>C p.F129L | Missense Mutation (SNP) | VAF 316/1796 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CACNA2D1 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 76/1372 reads (6%) | called by muse, mutect2
- CCDC96 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- EIF2AK4 | c.961dup p.M321Nfs*14 | Frame Shift Ins (INS) | VAF 747/1630 reads (46%) | called by mutect2, varscan2
- LARGE1 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 174/1622 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MAGEB1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 29/1122 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.223); called by muse, mutect2
- MFSD10 | c.1114+1G>T p.X372_splice | Splice Site (SNP) | VAF 43/872 reads (5%) | called by muse, mutect2
- OR2W1 | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 54/2122 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.217); called by muse, mutect2
- PTCH1 | c.1342_1346del p.L448Afs*47 | Frame Shift Del (DEL) | VAF 646/697 reads (93%) | called by mutect2, varscan2
- TMPRSS15 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 89/2450 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- ADAMDEC1 | c.537A>G p.E179= | Silent (SNP) | VAF 337/1769 reads (19%) | called by muse, mutect2, varscan2
- ALG13 | c.1833C>A p.L611= | Silent (SNP) | VAF 74/1544 reads (5%) | called by muse, mutect2
- CELSR1 | c.8532C>T p.G2844= | Silent (SNP) | VAF 410/899 reads (46%) | catalogued as rs202034570; called by muse, varscan2
- COL2A1 | c.3654C>T p.I1218= | Silent (SNP) | VAF 255/1353 reads (19%) | catalogued as rs780783419, COSV61533947; called by muse, mutect2, varscan2
- ESCO2 | c.1347C>A p.I449= | Silent (SNP) | VAF 258/1455 reads (18%) | called by muse, mutect2, varscan2
- MAN2B1 | c.774C>T p.P258= | Silent (SNP) | VAF 297/649 reads (46%) | called by muse, mutect2, varscan2
- OR52N4 | c.831C>A p.I277= | Silent (SNP) | VAF 571/1174 reads (49%) | called by muse, mutect2, varscan2
- PCLO | c.1371A>G p.G457= | Silent (SNP) | VAF 36/782 reads (5%) | called by muse, mutect2
- SPEG | c.3183G>A p.S1061= | Silent (SNP) | VAF 567/1243 reads (46%) | catalogued as rs201812370; called by muse, mutect2, varscan2
- WDR55 | c.768C>T p.I256= | Silent (SNP) | VAF 50/1170 reads (4%) | catalogued as rs766583334; called by muse, mutect2
- ZSCAN22 | c.696G>A p.A232= | Silent (SNP) | VAF 114/539 reads (21%) | catalogued as rs765803897; called by muse, mutect2, varscan2
- ANKRD30A | c.*22C>A | 3'UTR (SNP) | VAF 72/1891 reads (4%) | catalogued as COSV100653671; called by muse, mutect2
- C2orf78 | c.*32C>T | 3'UTR (SNP) | VAF 163/360 reads (45%) | catalogued as rs374844399; called by muse, mutect2, varscan2
- ECSCR | c.*82G>T | 3'UTR (SNP) | VAF 102/1280 reads (8%) | called by muse, mutect2
- FKBP9 | c.367+84A>G | Intron (SNP) | VAF 36/382 reads (9%) | called by muse, mutect2, varscan2
- MOK | c.1182+25C>T | Intron (SNP) | VAF 58/546 reads (11%) | catalogued as rs757409046, COSV51965760; called by muse, mutect2, varscan2
- SPATA31A1 | c.*34C>A | 3'UTR (SNP) | VAF 148/1247 reads (12%) | called by muse, mutect2, varscan2
- SZT2 | c.-31C>T | 5'UTR (SNP) | VAF 55/661 reads (8%) | called by muse, mutect2
